Surgical pathology report (de-identified scan), TCGA case TCGA-TM-A84I, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site The University of New South Wales, specimen TCGA-TM-A84I-01A (Primary Tumor).

[page 1 of 2]
At least 1 Final Result

Final

Page 2

SEX :M

DOCTOR :
DOC. ADDRESS :

D.O.B. :

COLL. DATE :
DATE RECEIVED :
WARD :
CONSULTANT :

HISTOPATHOLOGY REPORT

SPECIMEN:

- A. Brain.
- B. Left parietal tumour.

CLINICAL:

Left parietal tumour glioma.

MACROSCOPIC:

- A. Up to six soft smeared fragments 1mm to 5mm in size, pale grey in colour.

INTRA-OPERATIVE ASSESSMENT - FROZEN SECTION:

FSD. High grade glial tumour. Await permanent sections for definitive diagnosis.

BLOCK KEY:

1:tissue remaining from frozen section, 2:remaining tissue.

- B. Multiple fragments of tan tissue, measuring in aggregate approximately 10 x 15 x 3mm. (

MICROSCOPIC:

A, B. Specimens A and B will be discussed together as they show similar findings. Sections show multiple fragments in which the neural parenchyma has been extensively effaced by a malignant glioma. The neoplastic cells are irregularly scattered and crowded, possess pleomorphic and hyperchromatic nuclei with coarse chromatin and small nucleoli surrounded by indistinct eosinophilic cytoplasm. Frequent gemistocytes are seen throughout the tumour. Occasional mitotic figures are evident. Endothelial cell proliferation is not evident. There is no necrosis. Completed immunohistochemical studies show that the malignant cells are diffusely strongly positive for both GFAP and P53. The proliferation index, as measured by MIB-1 (Ki67), is variable and approximates 5-20%.

CONCLUSION:

A and B. Left parietal tumour: High grade glioma. Anaplastic astrocytoma, WHO III is felt to be the most likely diagnosis but ancillary studies are pending, including FISH [fluorescence in situ hybridization] studies. A supplementary report will be issued when these are available.

REGISTRAR:

PATHOLOGIST:

DATED: (

ELECTRONICALLY VALIDATED:

ICD-O-3

Astrocytoma, grade III 9401/3
Site Brain, supratentorial C71.0
① Brain, parietal lobe C71.3
9/10/2013

[page 2 of 2]
Patient Results

Anatomical Pathology results - Performed study

Corrected Results

Final Update

DOC. ADDRESS

COLL. DATE
DATE RECEIVED
WARD
CONSULTANT :

SUPPLEMENTARY REPORT

SPECIMEN:

- A. Brain.
- B. Left parietal tumour.

CLINICAL:

Left parietal tumour glioma.

FISH Studies:

FISH studies have been performed and show:

- No loss of 1p.
- No loss of 19q.
- EFGR amplification NOT detected.
- No amplification of N-MYC at 2p23-24 was detected. However, extra copies of chromosome 2 was detected in all cells analysed.

CONCLUSION:

A and B. Left parietal tumour: High grade glioma. Anaplastic astrocytoma, WHO III is felt to be the most likely diagnosis.

REGISTRAR:

PATHOLOGIST:

DATED:

ELECTRONICALLY VALIDATED:

----- END OF REPORT FOR

Page 2

DOCTOR
DOC. ADDRESS

COLL. DATE
DATE RECEIVED
WARD
CONSULTANT :

HISTOPATHOLOGY REPORT

SPECIMEN:

- A. Brain.
- B. Left parietal tumour.

CLINICAL:

Left parietal tumour glioma.

MACROSCOPIC:

- A. Up to six soft smeared fragments 1mm to 5mm in size, pale grey in colour.

Source: NCI Genomic Data Commons file 9e1713c7-55fb-4d3a-91f6-1960daeeeece (TCGA-TM-A84I.A028691E-342C-4D94-A22D-2049CE15FB17.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).